Somatic mutation profile of tumor specimen TCGA-BR-8369-01A (aliquot TCGA-BR-8369-01A-11D-2340-08) from TCGA case TCGA-BR-8369, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 76.8 years (28,051 days).
Specimen TCGA-BR-8369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63b0ef5a-a570-4964-a3ff-5f09e0dc5341.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8369-10A (Blood Derived Normal), aliquot TCGA-BR-8369-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddf063e3-2010-401b-a32c-10ef8147702f

The open-access MAF lists 214 somatic variants for this specimen: 164 protein-altering or splice-affecting, 45 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 146, Silent 45, Nonsense Mutation 8, Splice Site 6, Intron 3, Frame Shift Del 2, RNA 1, 3'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRKAG2 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121908991, CM051613, COSV55223940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TENT5D | c.205A>G p.S69G | Missense Mutation (SNP) | VAF 25/158 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV57634984, COSV57635195, COSV57638952; called by muse, mutect2, varscan2
- TP53 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 39/157 reads (25%) | hotspot (GDC flag); catalogued as rs1567555445, CS951538, COSV52663569, COSV52668477, COSV52702628; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.4598C>T p.S1533L | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs776920026, COSV54026755; called by muse, mutect2, varscan2
- ACACB | c.2738G>A p.G913E | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV58131197; called by muse, mutect2, varscan2
- ACTL9 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs868935067, COSV61005285; called by muse, mutect2
- ADAM21 | c.2003G>A p.G668E | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50790209; called by muse, mutect2
- ADPRH | c.631T>A p.Y211N | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV63694695; called by muse, mutect2, varscan2
- ALKBH8 | c.507A>T p.K169N | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV52834152, COSV52835172; called by muse, mutect2, varscan2
- ANO5 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs372674175; called by muse, mutect2, varscan2
- ANTXR1 | c.352A>C p.T118P | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58011425; called by muse, mutect2, varscan2
- APOB | c.12236G>A p.G4079E | Missense Mutation (SNP) | VAF 89/365 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV51929700; called by muse, mutect2, varscan2
- AQR | c.3977G>T p.R1326L | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV50031117; called by muse, mutect2, varscan2
- ARMC4 | c.913T>G p.F305V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53464015, COSV53466754; called by muse, mutect2, varscan2
- BCAM | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs750550926, COSV54301352; called by muse, mutect2, varscan2
- BICC1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs748986819, COSV65857929; called by muse, mutect2, varscan2
- BRPF1 | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 45/528 reads (9%) | catalogued as COSV57404008; called by muse, mutect2
- CACNA1S | c.4436C>T p.T1479M | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780785403, COSV62937744; called by muse, mutect2, varscan2
- CALCRL | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.687); catalogued as COSV66474166; called by muse, mutect2, varscan2
- CCDC158 | c.1948G>C p.D650H | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66355480; called by muse, mutect2
- CCDC28A | c.311T>G p.L104R | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60424701; called by muse, mutect2
- CCDC83 | c.1093T>G p.L365V (on ENST00000342404 / NM_001286159.2; = p.L396V on NM_173556.5) | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV54700922, COSV99721580; called by muse, mutect2, varscan2
- CCR7 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs568161538, COSV55848985; called by muse, mutect2, varscan2
- CD1A | c.904T>G p.F302V | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56860973, COSV56864683; called by muse, mutect2, varscan2
- CD80 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767373131, COSV51801822; called by muse, mutect2, varscan2
- CDH19 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.829); catalogued as rs1480423587, COSV50954631; called by muse, mutect2, varscan2
- CDH2 | c.1162T>A p.Y388N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.495); catalogued as COSV52275651; called by muse, mutect2, varscan2
- CELA3A | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545148620, COSV51582522; called by muse, mutect2
- CLIP1 | c.1523A>T p.E508V (on ENST00000620786 / NM_001247997.1; = p.E497V on NM_002956.2) | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV56799643; called by muse, mutect2, varscan2
- CNTN3 | c.2705-2A>G p.X902_splice | Splice Site (SNP) | VAF 6/111 reads (5%) | catalogued as COSV55166776; called by muse, mutect2
- CNTN6 | c.821A>G p.K274R | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs1171101315, COSV100610719, COSV63166804; called by muse, mutect2
- COL11A1 | c.5362T>G p.F1788V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs571497194, COSV100616746, COSV62177757; called by muse, mutect2, varscan2
- COL15A1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs746005741, COSV66642852, COSV66645456; called by muse, mutect2, varscan2
- COL7A1 | c.7270C>T p.R2424W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1189942401, COSV60393382; called by muse, mutect2
- CPED1 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV59999501; called by muse, mutect2, varscan2
- CS | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 74/535 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs754737940, COSV60832540; called by muse, mutect2, varscan2
- CYLC1 | c.190A>G p.R64G | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV61411046, COSV61412380; called by muse, mutect2
- CYP11B1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.284); catalogued as rs746083604, COSV52825877; called by muse, mutect2
- DCX | c.312T>G p.I104M | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57567482; called by muse, mutect2, varscan2
- DDR2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63370208; called by muse, mutect2, varscan2
- DLC1 | c.548T>G p.V183G | Missense Mutation (SNP) | VAF 38/910 reads (4%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV52296727; called by muse, mutect2
- DNAAF4 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1431977875, COSV58247667; called by muse, mutect2
- DSEL | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as COSV59490387; called by muse, mutect2, varscan2
- DST | c.8278G>A p.E2760K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV99760895; called by muse, mutect2, varscan2
- ELAVL2 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56359675; called by muse, mutect2, varscan2
- ENPP2 | c.2192T>G p.V731G (on ENST00000075322 / NM_001040092.3; = p.V783G on NM_006209.5) | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50011808; called by muse, mutect2, varscan2
- EVC | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 72/604 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202026284, COSV53830883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVL | c.1031C>T p.P344L (on ENST00000402714 / NM_001330221.2; = p.P346L on NM_016337.3) | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs773230379, COSV67374574; called by muse, mutect2
- F13B | c.1011G>T p.E337D | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100803525, COSV66373062; called by muse, mutect2, varscan2
- F5 | c.3949G>A p.G1317S | Missense Mutation (SNP) | VAF 54/706 reads (8%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.005); catalogued as rs149048805; ClinVar: uncertain significance; called by muse, mutect2
- FAM124B | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs756001279, COSV54739186; called by muse, mutect2, varscan2
- FAM13C | c.1541T>G p.L514R | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53242365; called by muse, mutect2, varscan2
- FAXC | c.659T>A p.L220H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV67601823; called by muse, mutect2, varscan2
- FOXF1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1293500536, COSV52285464; called by muse, mutect2, varscan2
- GAS2L3 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758071152, COSV57156640; called by muse, mutect2, varscan2
- GPBP1 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV53310820; called by muse, mutect2, varscan2
- GTF3C1 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780811770, COSV62239120; called by muse, mutect2
- HECW1 | c.1046-1G>T p.X349_splice | Splice Site (SNP) | VAF 27/96 reads (28%) | catalogued as COSV67826069; called by muse, mutect2, varscan2
- HLA-DQA2 | c.235A>C p.S79R | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV66564906; called by muse, varscan2
- HTR4 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs952435257, COSV58792288; called by muse, mutect2, varscan2
- IQSEC1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs536974018, COSV56222671; called by muse, mutect2, varscan2
- IRX6 | c.504C>A p.H168Q | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51859768; called by muse, mutect2, varscan2
- ITGA10 | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 133/610 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs782383906, COSV65196264; called by muse, varscan2
- KCNA3 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901232; called by muse, mutect2, varscan2
- KCNQ2 | c.2003C>A p.P668Q (on ENST00000359125 / NM_172107.4; = p.P640Q on NM_004518.6) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60542420; called by muse, mutect2, varscan2
- KCNS3 | c.1223A>G p.K408R | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV58406028; called by muse, mutect2, varscan2
- KIAA1109 | c.4406T>G p.L1469* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | catalogued as COSV52667014; called by muse, mutect2
- KIF16B | c.1419A>C p.L473F | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61703794; called by muse, mutect2
- KMT2A | c.3184T>C p.S1062P | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV63284007; called by muse, mutect2
- KRT2 | c.845T>G p.F282C | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59009692; called by muse, mutect2, varscan2
- KRT73 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.297); catalogued as COSV59838510; called by muse, mutect2, varscan2
- LDB2 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 7/169 reads (4%) | catalogued as rs982293354, COSV58764573, COSV58765570; called by muse, mutect2
- LRP1B | c.12394G>T p.G4132* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as COSV67201068; called by muse, mutect2, varscan2
- LRP1B | c.1638T>G p.D546E | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV67201071; called by muse, mutect2, varscan2
- LRRC4C | c.187G>T p.V63F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV53421615; called by muse, mutect2
- LRRC7 | c.4622C>T p.A1541V (on ENST00000651989 / NM_001370785.2; = p.A1461V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.784); catalogued as COSV50432195; called by muse, varscan2
- LRRK2 | c.5512G>T p.D1838Y | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as COSV54148479; called by muse, mutect2
- MACF1 | c.8977A>G p.T2993A | Missense Mutation (SNP) | VAF 11/132 reads (8%) | catalogued as COSV57113876; called by muse, mutect2
- MAFB | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as COSV64826481; called by muse, mutect2
- MAP2 | c.4371A>C p.E1457D | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV52286196; called by mutect2, varscan2
- MARCO | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59053228; called by muse, mutect2, varscan2
- MBD4 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV51444276; called by muse, mutect2, varscan2
- MGAT4C | c.1171A>G p.K391E | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV59831382; called by muse, mutect2
- MKRN3 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs200032750, COSV58809333; called by muse, mutect2, varscan2
- MSR1 | c.946A>C p.S316R | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as COSV50508804; called by muse, mutect2
- MUC16 | c.15622A>G p.S5208G | Missense Mutation (SNP) | VAF 50/318 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.135); catalogued as COSV67447728, COSV67479087; called by muse, mutect2, varscan2
- MYCBPAP | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV60406158, COSV60413432; called by muse, mutect2
- MYO3A | c.3119T>G p.L1040R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56324909; called by muse, mutect2, varscan2
- NAV1 | c.5405C>T p.P1802L | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV55215685; called by muse, mutect2
- NCAM2 | c.2334A>T p.R778S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53064973; called by muse, mutect2, varscan2
- NEBL | c.1424A>G p.K475R | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1225422071, COSV101009279, COSV65802133; called by muse, mutect2
- NMRK1 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV63111988; called by muse, mutect2, varscan2
- NTRK2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs144037140; called by muse, mutect2
- OBSCN | c.7643G>A p.S2548N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1226052184; called by muse, mutect2
- OPRK1 | c.439T>G p.F147V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55569305; called by muse, mutect2, varscan2
- OR10A4 | c.891A>T p.E297D | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.109); catalogued as COSV65841809; called by muse, mutect2
- OR4C12 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV58859624, COSV58860140; called by muse, mutect2, varscan2
- OR4C15 | c.188A>C p.E63A (on ENST00000314644; = p.E9A on NM_001001920.2) | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV58951804, COSV58951861; called by muse, mutect2, varscan2
- OR4M1 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 39/323 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as rs750128147, COSV60060257; called by muse, mutect2, varscan2
- OR5J2 | c.810A>C p.Q270H | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV56620506, COSV56620552; called by muse, mutect2, varscan2
- OSBPL3 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 50/337 reads (15%) | catalogued as rs1488793281, COSV57654786; called by muse, mutect2, varscan2
- OTOGL | c.4391T>C p.M1464T (on ENST00000547103; = p.M1455T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100088060; called by muse, mutect2
- PCDH19 | c.3360A>T p.K1120N (on ENST00000373034 / NM_001184880.2; = p.K1072N on NM_020766.3) | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV55260065; called by muse, mutect2, varscan2
- PDGFD | c.1034A>G p.K345R | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.519); catalogued as COSV56372748; called by muse, mutect2, varscan2
- PER2 | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs775687700, COSV54522361; called by muse, mutect2, varscan2
- PGF | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV99462836; called by muse, mutect2, varscan2
- PIGF | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.192); catalogued as COSV53231491; called by muse, mutect2, varscan2
- PKHD1L1 | c.10446G>T p.W3482C | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65739145, COSV65740271; called by muse, mutect2
- PLCE1 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as rs771124727, COSV53337446; called by muse, mutect2
- PLOD2 | c.284A>G p.E95G | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV51463426, COSV51468648; called by muse, mutect2, varscan2
- PLXNA4 | c.4024G>T p.G1342C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58114893; called by muse, mutect2
- PPFIA2 | c.3699A>C p.R1233S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV61026202; called by muse, mutect2
- PPP1R7 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV52144145; called by muse, mutect2, varscan2
- PRICKLE2 | c.1273G>A p.V425I (on ENST00000295902; = p.V369I on NM_198859.4) | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs568569832, COSV55764452; called by muse, mutect2, varscan2
- PRR5L | c.81G>T p.M27I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100287433; called by muse, mutect2, varscan2
- PSG6 | c.201G>C p.W67C | Missense Mutation (SNP) | VAF 54/475 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51831624; called by muse, mutect2, varscan2
- PTGER4 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV56720429; called by muse, mutect2, varscan2
- PTPRD | c.1252T>C p.S418P | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.709); catalogued as COSV61936067; called by muse, mutect2
- PTPRT | c.2314A>C p.R772= | Splice Region (SNP) | VAF 12/251 reads (5%) | catalogued as COSV61982822; called by muse, mutect2
- RAG1 | c.2417A>G p.E806G | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55024467; called by muse, mutect2
- RASIP1 | c.2885C>G p.S962C | Missense Mutation (SNP) | VAF 56/399 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as COSV55803570; called by muse, mutect2, varscan2
- RBM26 | c.982A>G p.M328V | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV57392904; called by muse, mutect2, varscan2
- RCAN1 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as COSV58249486; called by muse, mutect2, varscan2
- RFTN1 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 30/600 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1041994941, COSV61917848; called by muse, mutect2
- RS1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs61753171, CM981762, COSV66106075; ClinVar: not provided; called by muse, mutect2, varscan2
- RUBCNL | c.161T>A p.I54N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV59786757; called by muse, mutect2
- RYR3 | c.2418T>G p.Y806* | Nonsense Mutation (SNP) | VAF 20/169 reads (12%) | catalogued as COSV66782898; called by muse, mutect2, varscan2
- SACS | c.10571T>C p.L3524S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV66537522; called by muse, mutect2
- SARDH | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as rs891333543, COSV53832494; called by muse, mutect2, varscan2
- SEPTIN8 | c.881G>A p.S294N | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV51523565; called by muse, mutect2
- SLC17A1 | c.604T>C p.F202L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55077943; called by muse, mutect2, varscan2
- SLCO1B3 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53932142; called by muse, mutect2, varscan2
- SLITRK1 | c.2077T>C p.S693P | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV65674905; called by muse, mutect2
- SNX29 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs768184049, COSV60055155; called by muse, mutect2, varscan2
- SPON1 | c.1866G>C p.E622D | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV59959090; called by muse, mutect2, varscan2
- SRPRA | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 9/277 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303397344, COSV99702595; called by muse, mutect2
- ST6GAL2 | c.1235A>C p.K412T | Missense Mutation (SNP) | VAF 8/174 reads (5%) | PolyPhen possibly damaging (0.472); catalogued as rs1304601667, COSV62416250; called by muse, mutect2
- ST8SIA4 | c.868A>G p.R290G | Missense Mutation (SNP) | VAF 9/77 reads (12%) | PolyPhen possibly damaging (0.527); catalogued as COSV51508323, COSV51509997; called by muse, mutect2, varscan2
- STXBP5L | c.1363C>A p.L455I | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV56507394, COSV56512497; called by muse, mutect2
- SYNDIG1L | c.223G>C p.G75R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.605); catalogued as COSV59047257; called by muse, mutect2, varscan2
- TBR1 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 8/249 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67417535; called by muse, mutect2
- TEK | c.2524C>T p.R842C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs147231791, COSV66229109; called by muse, mutect2
- THSD7A | c.4154A>C p.E1385A | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as COSV69855578; called by muse, mutect2
- TIMELESS | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374029679; called by muse, mutect2, varscan2
- TMEM244 | c.120-2A>C p.X40_splice | Splice Site (SNP) | VAF 35/251 reads (14%) | catalogued as COSV63742664; called by muse, mutect2, varscan2
- TNNI1 | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 129/664 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs956135288, COSV60189102; called by muse, mutect2, varscan2
- TRIM71 | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs982336353, COSV101070479, COSV67470139; called by muse, mutect2, varscan2
- TRPS1 | c.1059T>G p.H353Q (on ENST00000220888 / NM_001330599.2; = p.H366Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV55250601, COSV99635299; called by muse, mutect2
- TRPS1 | c.108A>C p.E36D (on ENST00000220888 / NM_001330599.2; = p.E49D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV55232504; called by muse, mutect2, varscan2
- TRPV5 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs373410726, COSV54684276; called by muse, mutect2
- TTLL9 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV60590729; called by muse, mutect2
- TTN | c.78613T>C p.Y26205H (on ENST00000591111; = p.Y18781H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/114 reads (18%) | PolyPhen benign (0.006); catalogued as COSV59962069; called by muse, mutect2, varscan2
- UBQLNL | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV66492937; called by muse, mutect2, varscan2
- UNC79 | c.6023G>A p.C2008Y (on ENST00000393151 / NM_001346218.2; = p.C1831Y on NM_020818.5) | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359399768, COSV56380840; called by muse, mutect2, varscan2
- ZBTB25 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 27/217 reads (12%) | catalogued as COSV67198498; called by muse, mutect2, varscan2
- ZNF117 | c.35-2A>C p.X12_splice | Splice Site (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99276243; called by muse, mutect2, varscan2
- ZNF253 | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100849586, COSV63036794; called by muse, mutect2, varscan2
- ZNF423 | c.566G>A p.R189H (on ENST00000563137 / NM_001379286.1; = p.R181H on NM_015069.4) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778240903, COSV52182927; called by muse, mutect2, varscan2
- ZNF470 | c.398C>A p.S133* | Nonsense Mutation (SNP) | VAF 17/147 reads (12%) | catalogued as COSV57968258; called by muse, mutect2, varscan2
- ZNF586 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs752734548, COSV66972222; called by muse, mutect2, varscan2
- ACAT1 | c.835dup p.T279Nfs*10 | Frame Shift Ins (INS) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- BAZ2B | c.4575_4579delinsC p.N1526Ifs*23 | Frame Shift Del (DEL) | VAF 41/223 reads (18%) | called by pindel, varscan2*
- PEX11B | c.129del p.K43Nfs*10 | Frame Shift Del (DEL) | VAF 12/117 reads (10%) | called by mutect2, pindel
- PLB1 | c.1632+2_1632+6del p.X544_splice | Splice Site (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- ADCY5 | c.2859G>A p.T953= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs1476712867, COSV59196129; called by muse, mutect2, varscan2
- ADORA2A | c.981T>C p.H327= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs1419568853, COSV58378360; called by muse, mutect2, varscan2
- AHNAK | c.15726C>T p.G5242= | Silent (SNP) | VAF 28/286 reads (10%) | catalogued as COSV57208613; called by muse, mutect2
- AHNAK | c.7842C>T p.D2614= | Silent (SNP) | VAF 46/482 reads (10%) | catalogued as COSV57208623; called by muse, mutect2
- ANGEL2 | c.546T>C p.D182= | Silent (SNP) | VAF 32/156 reads (21%) | catalogued as COSV64737081; called by muse, mutect2, varscan2
- APBB1 | c.234G>A p.R78= | Silent (SNP) | VAF 37/350 reads (11%) | catalogued as COSV54974146; called by muse, mutect2, varscan2
- ARID3C | c.813C>A p.S271= | Silent (SNP) | VAF 27/233 reads (12%) | catalogued as COSV52406436, COSV52406918; called by muse, mutect2, varscan2
- ATP10A | c.2172G>A p.V724= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as COSV63515443; called by muse, mutect2
- BSN | c.1596G>A p.P532= | Silent (SNP) | VAF 47/296 reads (16%) | catalogued as rs749108010, COSV56515210, COSV56517971; called by muse, mutect2, varscan2
- C17orf98 | c.174C>T p.H58= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- CASR | c.853C>A p.R285= | Silent (SNP) | VAF 15/191 reads (8%) | catalogued as COSV56135391, COSV56135870; called by muse, mutect2
- CD2AP | c.51A>G p.E17= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV63760021; called by muse, mutect2, varscan2
- CRMP1 | c.1005C>T p.P335= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as COSV61479017; called by muse, mutect2, varscan2
- CSMD3 | c.1983A>G p.K661= (on ENST00000297405 / NM_001363185.1; = p.K557= on NM_052900.3) | Silent (SNP) | VAF 29/332 reads (9%) | catalogued as COSV52139570; called by muse, mutect2
- DCAF12 | c.165C>A p.V55= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV63512101; called by muse, mutect2, varscan2
- EMCN | c.672A>G p.P224= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as COSV56457608; called by muse, mutect2, varscan2
- ENPEP | c.1716T>C p.P572= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV54448723; called by muse, mutect2, varscan2
- FAM98C | c.933C>T p.N311= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as rs745545912, COSV53038483; called by muse, mutect2, varscan2
- FGF14 | c.342T>G p.V114= | Silent (SNP) | VAF 27/164 reads (16%) | catalogued as COSV65939224; called by muse, mutect2, varscan2
- FNTB | c.1170C>T p.P390= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs759157335, COSV55760667; called by muse, mutect2, varscan2
- IGHA2 | c.345G>A p.S115= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs782736298; called by muse, mutect2, varscan2
- KHDRBS3 | c.456A>G p.K152= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV63416177; called by muse, mutect2
- KIAA1191 | c.906C>T p.P302= | Silent (SNP) | VAF 33/276 reads (12%) | catalogued as rs778515194, COSV53798657; called by muse, mutect2, varscan2
- MAP6 | c.2049A>G p.Q683= | Silent (SNP) | VAF 54/202 reads (27%) | catalogued as COSV59074963; called by muse, mutect2, varscan2
- MMP3 | c.219G>A p.L73= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV55405550; called by muse, mutect2, varscan2
- NCKAP5 | c.1707C>A p.G569= | Silent (SNP) | VAF 12/137 reads (9%) | catalogued as COSV58436153; called by muse, mutect2
- NFASC | c.3315C>T p.I1105= (on ENST00000339876 / NM_001378329.1; = p.I1034= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/178 reads (7%) | catalogued as rs763350261, COSV58362427; called by muse, mutect2
- NOTCH4 | c.3729C>T p.Y1243= | Silent (SNP) | VAF 15/216 reads (7%) | catalogued as rs780232367, COSV66679728; called by muse, mutect2
- OR10Z1 | c.312T>C p.S104= | Silent (SNP) | VAF 28/398 reads (7%) | catalogued as COSV63524270; called by muse, mutect2
- OR6K2 | c.21C>A p.T7= | Silent (SNP) | VAF 15/156 reads (10%) | catalogued as COSV62743291; called by muse, mutect2
- PMPCA | c.525G>A p.R175= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as COSV53741059; called by muse, mutect2, varscan2
- PROKR1 | c.1092T>G p.S364= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as rs927904787, COSV58137037; called by muse, mutect2
- RHOBTB3 | c.276C>T p.G92= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as rs1488275827, COSV66101668; called by muse, mutect2, varscan2
- RYR2 | c.1119T>C p.T373= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as rs202231354, COSV100767104, COSV63675113; called by muse, mutect2, varscan2
- SH3BP4 | c.492G>A p.G164= | Silent (SNP) | VAF 9/204 reads (4%) | catalogued as COSV100749364; called by muse, mutect2
- SLC5A10 | c.252G>A p.A84= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs779038083, COSV58756569; called by muse, mutect2, varscan2
- SLITRK6 | c.1935T>C p.D645= | Silent (SNP) | VAF 10/219 reads (5%) | catalogued as COSV68389767; called by muse, mutect2
- SPEF2 | c.3504C>G p.L1168= | Silent (SNP) | VAF 13/300 reads (4%) | catalogued as COSV61546241; called by muse, mutect2
- SSUH2 | c.288C>A p.T96= | Silent (SNP) | VAF 40/155 reads (26%) | catalogued as rs905189041, COSV58029565; called by muse, mutect2, varscan2
- TBX22 | c.360G>T p.R120= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV64785384; called by muse, mutect2, varscan2
- TNR | c.3000C>T p.D1000= | Silent (SNP) | VAF 13/139 reads (9%) | catalogued as rs538886908, COSV54877648; called by muse, mutect2
- TRPM3 | c.444A>T p.G148= (on ENST00000357533 / NM_001366142.2; = p.G117= on NM_001007471.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/296 reads (5%) | catalogued as COSV62468789; called by muse, mutect2
- ZNF215 | c.1281A>G p.K427= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV53492389; called by muse, mutect2, varscan2
- ZNF772 | c.18G>A p.P6= | Silent (SNP) | VAF 21/371 reads (6%) | catalogued as rs775866183, COSV58410558; called by muse, mutect2
- ZNF799 | c.456C>T p.Y152= | Silent (SNP) | VAF 21/188 reads (11%) | catalogued as COSV70122205; called by muse, mutect2, varscan2
- CCNQP1 | n.385C>T | RNA (SNP) | VAF 18/105 reads (17%) | catalogued as rs768374567; called by muse, mutect2, varscan2
- DST | c.4297-2726A>G | Intron (SNP) | VAF 67/306 reads (22%) | catalogued as COSV99760896; called by muse, mutect2, varscan2
- FGFR3 | c.*793C>T | 3'UTR (SNP) | VAF 19/200 reads (10%) | catalogued as rs200589145, COSV53396928; called by muse, mutect2, varscan2
- LCMT1 | c.114-2497G>C | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- NALCN | c.2193-5302A>C | Intron (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2
